Somatic mutation profile of tumor specimen 0DHX2V from CCDI case PBBURC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,277 days).
Specimen 0DHX2V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7fb9386-6154-47ab-a388-bb9b68fbbba7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHX1W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b39c0fad-f301-4c13-8d09-01ccda1ffa4a

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO4 | c.2804G>A p.R935H (on ENST00000392977 / NM_001286615.2; = p.R900H on NM_178826.4) | Missense Mutation (SNP) | VAF 135/604 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs143188971; called by muse, mutect2, varscan2
- CR1 | c.5516G>A p.R1839H | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs571422599, COSV65458104; called by muse, mutect2, varscan2
- OR10AC1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious, low confidence (0.04); catalogued as rs1055290962; called by muse, mutect2, varscan2
- FCHO2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 40/765 reads (5%) | called by muse, mutect2
- SOWAHD | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- DNAH2 | c.11511C>T p.L3837= | Silent (SNP) | VAF 24/312 reads (8%) | catalogued as rs774903687, COSV66728772; called by muse, mutect2
- PRX | c.1461G>A p.P487= | Silent (SNP) | VAF 83/334 reads (25%) | catalogued as rs757009052, COSV52533114; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA12 | c.138A>G p.K46= | Silent (SNP) | VAF 68/403 reads (17%) | called by muse, mutect2
- ZAP70 | c.360C>T p.D120= | Silent (SNP) | VAF 41/225 reads (18%) | catalogued as rs768492740, COSV53854066; ClinVar: likely benign; called by muse, mutect2, varscan2
- XG | c.*24T>G | 3'UTR (SNP) | VAF 45/728 reads (6%) | called by muse, mutect2
- ZNF764 | c.*57C>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
